Somatic mutation profile of tumor specimen TCGA-VS-A8QC-01A (aliquot TCGA-VS-A8QC-01A-11D-A37N-09) from TCGA case TCGA-VS-A8QC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.3 years (18,743 days).
Specimen TCGA-VS-A8QC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df6219de-cf9c-4ed5-b788-e1ad5d2e8bdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8QC-10A (Blood Derived Normal), aliquot TCGA-VS-A8QC-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33b560e4-9177-4738-9d2c-d48073540dd3

The open-access MAF lists 159 somatic variants for this specimen: 117 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 39, Nonsense Mutation 12, Frame Shift Del 5, Splice Site 3, Intron 3, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993665271, COSV57247611; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.2762G>T p.C921F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100217850; called by muse, mutect2, varscan2
- ACOX3 | c.1302G>T p.M434I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100712071; called by muse, mutect2, varscan2
- ADAM7 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs747667436, COSV99445342; called by muse, mutect2, varscan2
- AGRN | c.3599T>A p.V1200D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101039173; called by muse, mutect2, varscan2
- AP3S2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1283927940, COSV100318689; called by muse, mutect2, varscan2
- APBA3 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as COSV57463542, COSV57463800; called by muse, mutect2, varscan2
- ARHGAP33 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs755300001, COSV99140521; called by muse, mutect2, varscan2
- B4GAT1 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as CM159476, COSV100240431; called by muse, mutect2, varscan2
- BAG6 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV52994045, COSV99277807; called by muse, mutect2, varscan2
- BAIAP3 | c.1171-1G>T p.X391_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100182016; called by muse, mutect2, varscan2
- BCL2L13 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100456467; called by muse, mutect2, varscan2
- BRD1 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV99350461; called by muse, mutect2
- BTAF1 | c.4954C>T p.Q1652* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99795947; called by muse, mutect2, varscan2
- C12orf43 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1176572996, COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- CACNA2D1 | c.801G>T p.L267F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100667604; called by muse, mutect2, varscan2
- CCDC54 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV99660348; called by muse, mutect2, varscan2
- CCDC9 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs748194748, COSV99699911; called by muse, mutect2, varscan2
- CCDC92 | c.922A>T p.K308* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99435995; called by muse, mutect2, varscan2
- CDH16 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100234017, COSV100234317; called by muse, mutect2
- CDH26 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99723159; called by muse, mutect2, varscan2
- CEP192 | c.5342G>C p.R1781T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1244845625, COSV100382364; called by muse, mutect2, varscan2
- CKMT2 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99562517; called by muse, mutect2, varscan2
- CLCN6 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV100412259; called by muse, mutect2, varscan2
- CLK2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1210319635, COSV100751952; called by muse, mutect2, varscan2
- CLUAP1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100489837; called by muse, mutect2, varscan2
- COG6 | c.1726G>C p.V576L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100743467; called by muse, mutect2, varscan2
- CPSF2 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100103181; called by muse, mutect2, varscan2
- CSMD3 | c.7838C>G p.S2613C (on ENST00000297405 / NM_001363185.1; = p.S2509C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as COSV99851233; called by muse, mutect2, varscan2
- CYP2C9 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs200183364, CM087577; called by muse, mutect2
- DAB2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100298460; called by muse, mutect2, varscan2
- DAPP1 | c.702C>G p.F234L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99597301; called by muse, mutect2
- DDR2 | c.1935C>G p.I645M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV100906951; called by muse, mutect2, varscan2
- DDX5 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.623); catalogued as rs782455211, COSV56748499, COSV56750795; called by muse, mutect2, varscan2
- DENND2D | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100718849, COSV62959071; called by muse, varscan2
- DENND4A | c.4831C>G p.P1611A | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV101475462; called by muse, mutect2, varscan2
- DLC1 | c.4480G>A p.E1494K (on ENST00000276297 / NM_001348081.2; = p.E1057K on NM_006094.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV99366167; called by muse, mutect2, varscan2
- DNAH17 | c.9404C>A p.A3135E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV101103807; called by muse, mutect2, varscan2
- DOCK2 | c.4389G>C p.W1463C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56994514, COSV99916193; called by muse, mutect2, varscan2
- EZHIP | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57957527; called by muse, mutect2, varscan2
- FAM151B | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99971945; called by muse, mutect2, varscan2
- FAM9A | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV101121380; called by muse, mutect2
- FOXK1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100196063; called by muse, mutect2
- FSCB | c.122A>C p.Y41S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV100470006; called by muse, mutect2, varscan2
- FSD2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100575207; called by muse, mutect2, varscan2
- GEMIN2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99158544; called by muse, mutect2, varscan2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2, varscan2
- HABP4 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771229420, COSV100928283; called by muse, mutect2, varscan2
- HSPG2 | c.5579C>G p.S1860W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV101021413; called by muse, mutect2, varscan2
- IGFBP7 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99825744; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1283G>C p.R428P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV100151535; called by muse, mutect2, varscan2
- ITIH3 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV101407177; called by muse, mutect2, varscan2
- ITPR2 | c.5648G>C p.R1883T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV101190267; called by muse, mutect2, varscan2
- JMJD1C | c.3320G>C p.R1107T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100550916; called by muse, mutect2, varscan2
- KHNYN | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99250207; called by muse, mutect2, varscan2
- KIAA1217 | c.2730G>C p.L910F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.316); catalogued as COSV100287464; called by muse, mutect2, varscan2
- KLHDC7B | c.1027C>T p.P343S (on ENST00000395676; = p.P984S on NM_138433.5) | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV101193001; called by muse, mutect2, varscan2
- LARGE1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as COSV61667347; called by muse, mutect2, varscan2
- LBP | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.679); catalogued as COSV99461443; called by muse, mutect2, varscan2
- LINGO2 | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV100431366, COSV58060699; called by muse, mutect2, varscan2
- LRRK2 | c.6253G>A p.E2085K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); catalogued as COSV100111413; called by muse, mutect2, varscan2
- MAP3K14 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100766589, COSV60923649; called by muse, mutect2, varscan2
- MAP4K3 | c.1695G>A p.W565* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV55718026, COSV99811267; called by muse, mutect2, varscan2
- METTL25 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942773; called by muse, mutect2, varscan2
- MFSD8 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99614758; called by muse, mutect2, varscan2
- MROH1 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100396218; called by muse, mutect2, varscan2
- MS4A14 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100280783; called by muse, mutect2, varscan2
- NCAM1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV57516040; called by muse, mutect2, varscan2
- NELL1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs751417061, COSV100125943; called by muse, mutect2, varscan2
- NEMP1 | c.780G>A p.M260I (on ENST00000300128 / NM_001130963.2; = p.M187I on NM_015257.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100272372; called by muse, mutect2, varscan2
- NEMP1 | c.576G>A p.M192I (on ENST00000300128 / NM_001130963.2; = p.M119I on NM_015257.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100272376; called by muse, mutect2, varscan2
- NFAT5 | c.2567G>C p.R856T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs772781064, COSV100591338; called by muse, varscan2
- NFAT5 | c.3410C>G p.S1137* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100591340; called by muse, mutect2, varscan2
- NHS | c.2779C>T p.L927F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101197081; called by muse, mutect2, varscan2
- NOL4L | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV100675738; called by muse, mutect2, varscan2
- OVCH1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs754703697, COSV100549344; called by muse, mutect2, varscan2
- P2RY12 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs148966366, COSV56373924; called by muse, mutect2, varscan2
- PAPPA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs576620013, COSV62772155; called by muse, mutect2, varscan2
- PBXIP1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV100870140; called by muse, mutect2, varscan2
- PDCD6 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as rs545985005, COSV99373152; called by muse, mutect2, varscan2
- PKHD1L1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV101007056, COSV65744385; called by muse, mutect2, varscan2
- PLCB4 | c.1707C>G p.I569M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV99597231; called by muse, mutect2, varscan2
- PPP4R3A | c.2425G>A p.D809N (on ENST00000554943 / NM_001366432.1; = p.D796N on NM_001284280.1) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV100466681, COSV61505550; called by muse, mutect2, varscan2
- PTPN13 | c.3892G>A p.D1298N (on ENST00000411767 / NM_080683.3; = p.D1279N on NM_006264.3) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as rs750629084, COSV100365593; called by muse, mutect2, varscan2
- RELN | c.1777T>A p.F593I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100635135; called by muse, mutect2, varscan2
- RGS12 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100137148; called by muse, mutect2, varscan2
- RPL10 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV99186417; called by muse, mutect2, varscan2
- RYR1 | c.8694C>T p.G2898= | Splice Region (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100617294; called by muse, mutect2, varscan2
- SAMD4A | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99200872; called by muse, mutect2, varscan2
- SASH3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV63555972; called by muse, mutect2
- SCN3A | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV99328897; called by muse, mutect2, varscan2
- SEMA4D | c.1761G>C p.W587C | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358938; called by muse, mutect2
- SH2D4A | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754653430, COSV56124543, COSV99745310; called by muse, mutect2, varscan2
- SLC27A5 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54019105; called by muse, mutect2, varscan2
- SLC28A3 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs772453182, COSV100883374; called by muse, mutect2, varscan2
- SLC30A1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100879179; called by muse, mutect2, varscan2
- SMC6 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 7/116 reads (6%) | catalogued as COSV61172316; called by muse, mutect2
- STX3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276340; called by muse, mutect2, varscan2
- SUSD1 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs748152321, COSV100813531; called by muse, mutect2, varscan2
- TOMM70 | c.1793C>G p.A598G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV99424676; called by muse, mutect2, varscan2
- USP53 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99918134; called by muse, mutect2
- WDR64 | c.2862-1G>C p.X954_splice | Splice Site (SNP) | VAF 17/109 reads (16%) | catalogued as COSV100844142; called by muse, mutect2, varscan2
- XDH | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1365775355, COSV101052510; called by muse, mutect2, varscan2
- YIPF2 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99450409; called by muse, mutect2, varscan2
- ZDHHC7 | c.741C>G p.N247K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.319); catalogued as rs139969155, COSV100569017; called by muse, mutect2, varscan2
- ZEB1 | c.3316G>C p.G1106R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1248076108, COSV100315286, COSV58051488; called by mutect2, varscan2
- ZNF436 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100011404; called by muse, mutect2, varscan2
- ZNF600 | c.1973G>C p.R658T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.849); catalogued as COSV100593133, COSV57741329; called by muse, mutect2, varscan2
- ACACA | c.6075del p.E2026Kfs*5 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- FAM133A | c.271del p.R91Efs*67 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- JAG2 | c.3127del p.Q1043Rfs*327 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | called by mutect2, pindel, varscan2
- JAKMIP2 | c.549_556del p.D183Efs*2 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- NSD1 | c.3875_3876dup p.A1293Lfs*17 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- SPDL1 | c.1137-1G>A p.X379_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TFAP2E | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- TMEM102 | c.733_751del p.E245Rfs*31 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.3426C>T p.L1142= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99927127; called by muse, mutect2, varscan2
- CACNA1F | c.2829G>A p.L943= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100545502; called by muse, mutect2, varscan2
- CCDC136 | c.1884G>C p.L628= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99923388; called by muse, mutect2, varscan2
- CFAP92 | c.1107G>C p.L369= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99415008; called by muse, mutect2, varscan2
- CPB1 | c.1089C>T p.D363= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs767732346, COSV99294599; called by muse, mutect2
- CYP2D6 | c.1224C>G p.V408= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV100637412; called by muse, mutect2, varscan2
- EEFSEC | c.612G>A p.E204= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99631633; called by muse, mutect2, varscan2
- EPHA5 | c.2343G>C p.L781= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99901906; called by muse, mutect2
- FLNA | c.4272C>G p.L1424= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100775384; called by muse, mutect2, varscan2
- GPR35 | c.510C>T p.F170= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100166385; called by muse, mutect2, varscan2
- HECTD1 | c.2577C>G p.L859= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV65991305; called by muse, mutect2, varscan2
- HSPG2 | c.7116C>G p.V2372= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV101021410; called by muse, mutect2, varscan2
- HSPG2 | c.6576C>G p.L2192= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV101021412; called by muse, mutect2, varscan2
- IGF1R | c.1818C>T p.T606= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs182353595; called by muse, mutect2, varscan2
- KLHL1 | c.1920C>T p.V640= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs372198907; called by muse, mutect2, varscan2
- KLHL17 | c.1773C>G p.L591= | Silent (SNP) | VAF 70/245 reads (29%) | catalogued as COSV100647635; called by muse, mutect2, varscan2
- MAD2L2 | c.108C>G p.V36= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99336295; called by muse, mutect2, varscan2
- MFN1 | c.1074A>C p.V358= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99764764; called by muse, mutect2
- MFSD13A | c.1263G>C p.L421= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1049928844, COSV99488112; called by muse, mutect2, varscan2
- OTUD6B | c.96C>A p.G32= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99576128; called by muse, mutect2, varscan2
- PKD1 | c.7798C>T p.L2600= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs1232997513, COSV99239287; called by muse, mutect2, varscan2
- PPEF1 | c.1368A>C p.A456= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100584130; called by muse, mutect2, varscan2
- PRKDC | c.2829C>G p.G943= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100043443; called by muse, mutect2, varscan2
- RAB4A | c.516A>G p.R172= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100797110; called by muse, mutect2, varscan2
- RAB5B | c.123C>T p.V41= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100822204; called by muse, mutect2, varscan2
- RASGEF1B | c.204C>T p.L68= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs201973639; called by muse, mutect2, varscan2
- RTF1 | c.1098G>T p.R366= | Silent (SNP) | VAF 57/87 reads (66%) | catalogued as COSV101048321, COSV67477748; called by muse, mutect2, varscan2
- SLC39A6 | c.33G>C p.L11= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99310010; called by muse, mutect2, varscan2
- SLC3A2 | c.1662C>T p.I554= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100101555; called by muse, mutect2, varscan2
- SNAP25 | c.76C>T p.L26= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99655430; called by muse, mutect2
- STEAP2 | c.1411C>T p.L471= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99840740; called by muse, mutect2
- TANC2 | c.3741G>T p.L1247= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV101267703; called by muse, mutect2, varscan2
- TMEM108 | c.1047C>T p.S349= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV100419735; called by muse, mutect2, varscan2
- TRAV30 | c.93G>A p.V31= | Silent (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- TTC7A | c.1881G>A p.L627= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99767071; called by muse, mutect2, varscan2
- TYK2 | c.1983C>T p.L661= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99315603; called by muse, mutect2, varscan2
- ZNF25 | c.915G>A p.Q305= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100224830; called by muse, mutect2, varscan2
- ZNF527 | c.1053C>T p.I351= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100648795; called by muse, mutect2, varscan2
- ZNRF4 | c.105G>A p.S35= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs757342883, COSV55772947; called by muse, mutect2
- CAMSAP3 | c.621+207G>T | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99352259; called by mutect2, varscan2
- HIF3A | c.877+87G>C | Intron (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- MBNL1 | c.174+40481T>C | Intron (SNP) | VAF 12/39 reads (31%) | catalogued as rs772414146, COSV99221437; called by muse, mutect2, varscan2
